Surgical pathology report (de-identified scan), TCGA case TCGA-43-7657, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-7657-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

Final Surgical Pathology Report

Procedure [REDACTED]

Diagnosis

A. Right upper lobe, wedge resection:

Squamous cell carcinoma, moderately differentiated, 2.1 cm, margins uninvolved.

B. Level 10 lymph node, resection:

No metastasis identified in one lymph node (0/1).

C. Lung, right upper lobe, lobectomy:

No carcinoma identified.

No evidence of metastasis in 3 lymph nodes (0/3).

D. R4 lymph nodes, resection:

No metastasis identified in 7 lymph nodes (0/7).

E. Subcarinal lymph nodes, resection:

No metastasis identified in 4 lymph nodes (0/4).

[page 2 of 4]
Microscopic Description:

Microscopic examination performed.

A. Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Primary tumor (pT): 2.1 cm, pT1

Margins of resection: Uninvolved

Direct extension of tumor: Not identified

Venous (large vessel) invasion: Not identified

Arterial (large vessel) invasion: Not identified

Lymphatic (small vessel) invasion: Not identified

Regional lymph nodes (pN): Negative, pN0

Distant metastasis (pM): Cannot be evaluated by this specimen, pMX

Other findings: None

B. Level 10 lymph node demonstrates no evidence of metastasis in one lymph node.

C. The remainder of the right upper lobe demonstrates no evidence of malignancy. 3 lymph nodes are negative for metastatic disease.

D. The R4 lymph nodes demonstrate 7 lymph nodes with no evidence of metastasis.

E. The subcarinal lymph nodes demonstrate 4 lymph nodes with no evidence of metastasis.

[page 3 of 4]
Specimen

- A. Right upper lobe wedge
- B. Level 10
- C. Right upper lobe
- D. R. 4
- E. Subcarinal

Clinical Information

Right lung mass

Intraoperative Consultation

AFS1, AFS2: Lung mass, excision: Non-small cell carcinoma, favor squamous cell carcinoma

Gross Description

gross A. Container "A" is labeled with the patient's name, medical record number and "right upper lobe wedge". The specimen consists of a single pink to tan piece of wedge-shaped lung tissue measuring 12.2 x 6.5 x 2.5 cm in greatest dimensions. There is a 12 cm staple line present. The pleural surface is puckered. This region is inked and sectioned. On cut section there is a soft necrotic appearing tan - black mass which measures 2.1-1.5 x 1.5 cm in greatest dimensions. A portion is submitted for tissue procurement. The staple line is greater than 1.5 cm from the mass. Representative sections submitted AFS1, FS2, A1 - A3: lung mass entirely submitted; A4 - surgical margin; A5 - non-neoplastic lung

[page 4 of 4]
B. Received fresh labeled "level 10" is a 0.8 cm soft tan to gray tissue which is bisected and entirely submitted in one block.

C. Received fresh labeled "right upper lobe" is a 156 g, 17.0 x 7.8 x 3.2 cm lobectomy specimen with attached 1.2 cm in length, 1.8 x 1.0 cm in diameter bronchial stump. Several staple lines are present. The staple line along the lateral aspect of the specimen is removed and the underlying surface is inked blue. On sectioning, the parenchyma throughout the specimen is spongiform tan-red and no residual lesion or abnormality is identified grossly. 3 soft tan-gray tissues in keeping with lymph nodes ranging from 0.5-0.9 cm are recovered from the hilum.

Summary: 1 - bronchial margin; 2 - vascular margins; 3 through 6 - site of staple line; 7 through 9 - random parenchyma; 10 - 3 lymph nodes

D. Received fresh labeled "R 4" is a 2.1 x 1.5 x 0.5 cm aggregate of fragmented soft tan-gray tissue admixed with a scant amount of adipose tissue.

E. Received fresh labeled "subcarinal" are 4 soft tan-gray tissues ranging from 0.5-0.7 cm.

Source: NCI Genomic Data Commons file 95367a69-27b9-4518-917a-85ad75eea2bc (TCGA-43-7657.24615CEB-B7AA-472D-9DC0-7AF1FDF9F8C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).